Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3AE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3AE-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

ICA-0-3
Melanoma, NOS 8720/3
Site: lymph node, groin C77.4 /w 9/21/11

CLINICAL DETAILS

- L calf melanoma with negative SNB. Now recurrence L groin. Today - L iliac / obturator/ inguinal LN dissection

MACROSCOPIC DESCRIPTION

(Dr

Three specimens received.

1. "LEFT MARGINAL GROIN DISSECTION, LOOP - PROXIMAL VEIN, LONG - DISTAL LONG SAPHENOUS VEIN". A piece of fibrofatty tissue, 170 x 70 x 45mm. There is an attached ellipse of skin, 55 x 12mm to a depth of 3mm. The skin is 12mm from the lateral margin and 40mm from the distal margin. The skin is presumed to be the anterior aspect. On the surface of the skin there is a ? longitudinal scar, 5mm in length. On the opposite side (posterior aspect) there is a pigmented lymph node 25 x 22 x 20mm. The lymph has already been bisected (?for tumour banking). The lymph node is 7mm from the distal margin and 12mm from the medial margin macroscopically. The cut surface of the lymph node is pigmented with a round pale area, 10 x 7mm, which abuts on the posterior aspect of the node. Situated 5mm above the node there is a looped stitch (proximal vein). 45mm distal to the lymph node there is a long stitch (distal long saphenous vein). The proximal/ distal orientation of the specimen is based on these stitch markings. The surgical margin of the node is inked blue. This specimen is serially sliced transversely from proximal to distal.

Macroscopic photographs taken (

- 1A. Representative section of large lymph node showing inked surgical margin.
- 1B. Representative section of skin showing scar.
- 1C. One lymph node divided into four.
- 1D. One lymph node bisected.
- 1E. Two lymph nodes.
- 1F. One lymph node trisected.
- 1G. One lymph node trisected.
- 1H. Two lymph nodes.
- 1I. One lymph node.
- 1K. Four lymph nodes.

2. "LEFT PELVIC LYMPH NODE". Fibrofatty tissue, 50 x 40 x 25mm. Ten lymph nodes identified, the largest 20 x 15 x 10mm.

- 2A. One lymph node bisected.
- 2B. One lymph node bisected.
- 2C. Two lymph nodes each bisected.
- 2D. Four lymph nodes.

[page 2 of 2]
Requested by

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

2E. Three lymph nodes.

3. "CONTENTS OF LEFT FEMORAL CANAL". A piece of fibrofatty tissue, 20 x 10 x 5mm. No lymph nodes identified. All embedded in block 3A.

MICROSCOPIC REPORT

1. "LEFT MARGINAL GROIN DISSECTION, LOOP - PROXIMAL VEIN, LONG - DISTAL LONG SAPHENOUS VEIN".

The sections show a lymph node which has been largely replaced by deposit of malignant melanoma. The tumour consists of spindle cells with finely granular brown cytoplasmic pigment. Frequent mitotic figures are present, up to 6/mm². No extranodal spread is identified. The tumour is clear of the margins; the nearest margin (deep) is clear by 1mm. The other twelve lymph nodes identified in this specimen show non-specific reactive changes only. The skin shows an area of dermal scarring.

2. "LEFT PELVIC LYMPH NODE".

The eleven lymph nodes identified show non-specific reactive changes only. No evidence of malignancy is seen.

3. "CONTENTS OF LEFT FEMORAL CANAL".

The sections show adipose tissue only. No lymph nodes are identified.

SUMMARY

1. LEFT GROIN:

- Malignant melanoma (1/13 LN).

/

2. LEFT PELVIC LYMPH NODES:

- No evidence of malignancy (0/11 LN).

/

3. LEFT FEMORAL CANAL:

- Adipose tissue only.

REPORTED BY: Prof.

Source: NCI Genomic Data Commons file 81a15bee-a248-49d0-bb59-544da6f8144b (TCGA-EE-A3AE.E31E9171-62C3-4DD9-B756-62D4DE599976.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).